Somatic mutation profile of tumor specimen MMRF_2515_1_BM_CD138pos (aliquot MMRF_2515_1_BM_CD138pos_T1_KHS5U_K15182) from MMRF case MMRF_2515, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 87.1 years (31,810 days).
Specimen MMRF_2515_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 676c6095-cf55-4b28-a915-3c021c648bb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2515_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2515_1_PB_WBC_C3_KHS5U_K15181; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0887aa39-3467-4b6a-a15d-958d317c4331

The open-access MAF lists 90 somatic variants for this specimen: 33 protein-altering or splice-affecting, 16 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 23, Silent 16, Intron 7, 5'UTR 5, 3'Flank 3, Nonsense Mutation 2, RNA 2, Splice Site 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF6 | c.1337A>T p.N446I | Missense Mutation (SNP) | VAF 94/198 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1464926161; called by muse, mutect2, varscan2
- CEBPZ | c.1955A>G p.K652R | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as rs764007712; called by muse, mutect2, varscan2
- CSMD3 | c.10577G>A p.G3526E (on ENST00000297405 / NM_001363185.1; = p.G3357E on NM_052900.3) | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV52240954; called by muse, mutect2, varscan2
- DIAPH3 | c.1098G>A p.M366I (on ENST00000400324 / NM_001042517.2; = p.M103I on NM_030932.3) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99932699; called by muse, mutect2, varscan2
- FLYWCH1 | c.1171C>T p.R391* (on ENST00000253928 / NM_001308068.2; = p.R390* on NM_020912.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/99 reads (44%) | catalogued as rs563631527; called by muse, mutect2, varscan2
- H4-16 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV63762454; called by muse, mutect2, varscan2
- IGLL5 | c.206+1G>A p.X69_splice | Splice Site (SNP) | VAF 9/12 reads (75%) | catalogued as rs769556163, COSV73249537, COSV73250119, COSV73251144; called by muse, varscan2
- IL12RB1 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV59097884; called by muse, mutect2, varscan2
- MAGED1 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV58516334; called by muse, mutect2, varscan2
- MAT1A | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs754347805, COSV64745751; called by muse, mutect2, varscan2
- MS4A6A | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.312); catalogued as rs370469349; called by muse, mutect2, varscan2
- MYO16 | c.2674A>G p.N892D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749320116; called by muse, mutect2, varscan2
- PCDH10 | c.2224A>C p.K742Q | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs752199952; called by muse, mutect2, varscan2
- PCDHAC1 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 271/451 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53853503; called by muse, mutect2, varscan2
- RNF128 | c.1153+1G>A p.X385_splice (on ENST00000255499 / NM_194463.2; = p.X359_splice on NM_024539.3) | Splice Site (SNP) | VAF 103/253 reads (41%) | catalogued as rs1156474179, COSV55255254; called by muse, mutect2, varscan2
- TAS2R41 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 116/217 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.119); catalogued as COSV68765918; called by muse, mutect2, varscan2
- ATRX | c.6482A>C p.Y2161S | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CBY2 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- CD300C | c.503G>A p.S168N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- CLCN2 | c.1781G>C p.S594T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTN3 | c.2244G>A p.W748* | Nonsense Mutation (SNP) | VAF 59/161 reads (37%) | called by muse, mutect2, varscan2
- DSC2 | c.1510A>T p.S504C | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- HELT | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IGKJ4 | chr2:88860921 del AGCCAC | Missense Mutation (DEL) | VAF 36/62 reads (58%) | called by pindel, varscan2
- IRF4 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0319 | c.2405A>T p.D802V | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MELK | c.823A>G p.S275G | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MYH8 | c.385A>C p.N129H | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PRKD1 | c.2211G>C p.K737N | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- RPGRIP1 | c.1556T>C p.L519P | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOPAZ1 | c.3943G>C p.D1315H | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAF3 | c.1464G>T p.W488C | Missense Mutation (SNP) | VAF 71/96 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIML1 | c.1395C>G p.N465K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf120 | c.828C>T p.I276= | Silent (SNP) | VAF 88/194 reads (45%) | catalogued as rs200543036; called by muse, mutect2, varscan2
- C2orf16 | c.2385C>T p.A795= | Silent (SNP) | VAF 112/321 reads (35%) | called by muse, mutect2, varscan2
- CDH10 | c.414G>A p.R138= | Silent (SNP) | VAF 109/205 reads (53%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.2436G>A p.Q812= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as rs760246017; called by muse, mutect2
- ENPEP | c.147C>T p.G49= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs775120757, COSV54450020; called by muse, mutect2, varscan2
- FOXO1 | c.1967G>A p.*656= | Silent (SNP) | VAF 70/167 reads (42%) | called by muse, mutect2, varscan2
- GABRG2 | c.54A>G p.V18= | Silent (SNP) | VAF 123/184 reads (67%) | catalogued as rs200838780; called by muse, mutect2, varscan2
- GRIPAP1 | c.2076C>T p.S692= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- KAT5 | c.306C>T p.S102= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as rs767056692, COSV57729400; called by muse, mutect2, varscan2
- KCNH1 | c.1863G>A p.V621= (on ENST00000271751 / NM_172362.3; = p.V594= on NM_002238.4) | Silent (SNP) | VAF 109/192 reads (57%) | catalogued as rs1262993995; called by muse, mutect2, varscan2
- LRBA | c.1026A>G p.K342= | Silent (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- SENP6 | c.331T>C p.L111= | Silent (SNP) | VAF 128/295 reads (43%) | called by muse, mutect2, varscan2
- SLC16A9 | c.1077T>A p.L359= | Silent (SNP) | VAF 69/132 reads (52%) | called by muse, mutect2, varscan2
- TCTE1 | c.528G>A p.V176= | Silent (SNP) | VAF 76/226 reads (34%) | called by muse, mutect2, varscan2
- TNFRSF19 | c.1074G>A p.G358= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as rs1186036666; called by muse, mutect2, varscan2
- ZNF585B | c.750G>A p.A250= | Silent (SNP) | VAF 96/263 reads (37%) | catalogued as rs144159375; called by muse, mutect2, varscan2
- ACTR3 | c.*3505T>G | 3'UTR (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- ADSS1 | c.*193A>G | 3'UTR (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- AGPS | c.*917A>C | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- C10orf71 | c.*57C>G | 3'UTR (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- CACNA2D2 | chr3:50362765 C>T | 3'Flank (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- CCDC136 | chr7:128791882 G>A | 5'Flank (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- CCT3 | c.-15C>G | 5'UTR (SNP) | VAF 65/247 reads (26%) | catalogued as rs753112621; called by muse, mutect2, varscan2
- CXCR5 | c.51+1877T>G | Intron (SNP) | VAF 56/113 reads (50%) | called by muse, mutect2, varscan2
- DIP2A | c.-117C>T | 5'UTR (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- ENOSF1 | chr18:673067 T>C | 3'Flank (SNP) | VAF 135/299 reads (45%) | called by muse, mutect2, varscan2
- ERCC6 | c.*317G>T | 3'UTR (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- EXOC7 | c.1582+165C>T | Intron (SNP) | VAF 3/39 reads (8%) | catalogued as rs1157295115; called by muse, mutect2
- FGD6 | c.*2161T>C | 3'UTR (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- HNF1A | c.1501+125G>A | Intron (SNP) | VAF 58/101 reads (57%) | catalogued as rs534579147; called by muse, mutect2
- HPS5 | c.*960T>A | 3'UTR (SNP) | VAF 30/50 reads (60%) | catalogued as rs886048071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL36B | c.*45T>G | 3'UTR (SNP) | VAF 74/178 reads (42%) | called by muse, mutect2, varscan2
- IQCE | c.*1667G>T | 3'UTR (SNP) | VAF 26/105 reads (25%) | called by muse, mutect2, varscan2
- IQUB | c.*315C>G | 3'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs961527576; called by muse, mutect2, varscan2
- LARS1 | c.*1028C>T | 3'UTR (SNP) | VAF 38/125 reads (30%) | called by muse, mutect2, varscan2
- LINC00293 | n.425+859T>C | Intron (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- LL22NC03-63E9.3 | n.2261C>A | RNA (SNP) | VAF 28/68 reads (41%) | called by muse, varscan2
- MAP3K19 | c.3920+137G>A | Intron (SNP) | VAF 85/218 reads (39%) | called by muse, mutect2, varscan2
- MRS2 | c.*1823C>A | 3'UTR (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- MYO1E | c.-109G>A | 5'UTR (SNP) | VAF 50/93 reads (54%) | called by muse, mutect2, varscan2
- NADSYN1 | c.*266A>G | 3'UTR (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- NAPRT | c.*52C>T | 3'UTR (SNP) | VAF 99/207 reads (48%) | catalogued as rs564955660; called by muse, mutect2, varscan2
- NLN | c.*3279G>A | 3'UTR (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- NPR3 | c.*589C>A | 3'UTR (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- PKD1L2 | n.2797G>A | RNA (SNP) | VAF 41/55 reads (75%) | catalogued as rs749316899; called by muse, mutect2, varscan2
- PRDM15 | c.-293C>T | 5'UTR (SNP) | VAF 30/54 reads (56%) | catalogued as rs766040068; called by muse, mutect2, varscan2
- PTPRR | c.628-412del | Intron (DEL) | VAF 44/163 reads (27%) | called by mutect2, pindel, varscan2
- RAP2B | c.*57T>G | 3'UTR (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- S100A7A | chr1:153419692 T>C | 3'Flank (SNP) | VAF 18/84 reads (21%) | catalogued as rs748159636; called by muse, mutect2, varscan2
- SEPTIN9 | c.722-6622G>C | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- TEK | c.-205G>C | 5'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- TENT5D | c.*1047T>C | 3'UTR (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- THBD | c.*1502G>T | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- TOR1B | c.*767del | 3'UTR (DEL) | VAF 4/41 reads (10%) | catalogued as rs1287033793; called by pindel, varscan2
- TSPAN9 | c.*695G>A | 3'UTR (SNP) | VAF 29/67 reads (43%) | catalogued as rs1489023966; called by muse, mutect2, varscan2
- WNT3A | c.*530G>A | 3'UTR (SNP) | VAF 96/169 reads (57%) | catalogued as rs1188643297; called by muse, mutect2, varscan2
- ZNF488 | c.*1516C>A | 3'UTR (SNP) | VAF 49/189 reads (26%) | called by muse, mutect2, varscan2
